Somatic mutation profile of tumor specimen 0DW42F from CCDI case PBCNSV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.8 years (5,768 days).
Specimen 0DW42F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fd2e7c9-711e-48c5-aea0-c3fe13017027.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW41R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf4b9dcf-a342-482c-949c-149bd75aa721

The open-access MAF lists 40 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Intron 5, 5'UTR 2, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 108/348 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 223/248 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CIC | c.1717G>A p.V573M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs1273825689; called by muse, mutect2, varscan2
- FAM83H | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV66354454; called by muse, mutect2, varscan2
- NF1 | c.2023G>T p.G675* | Nonsense Mutation (SNP) | VAF 113/308 reads (37%) | catalogued as rs779546178, COSV100648178, COSV62206641, COSV62221974; called by muse, mutect2
- OLFM3 | c.211G>T p.A71S (on ENST00000338858 / NM_001288821.1; = p.A51S on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/413 reads (35%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.992); catalogued as COSV58800576; called by muse, mutect2, varscan2
- OR5H1 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 137/445 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV63401933; called by muse, mutect2, varscan2
- SCP2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 148/380 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs754455235; called by muse, mutect2, varscan2
- SGK3 | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as rs1376841391; called by muse, mutect2
- TEKT3 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763618773, COSV58627231; called by muse, mutect2
- AL441992.2 | c.335T>A p.V112E | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- ARID4A | c.3720G>A p.M1240I | Missense Mutation (SNP) | VAF 98/175 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ASNS | c.1291T>A p.S431T | Missense Mutation (SNP) | VAF 46/649 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); called by muse, mutect2
- CCDC73 | c.437A>T p.K146M | Missense Mutation (SNP) | VAF 10/289 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- CELSR1 | c.7665T>G p.H2555Q | Missense Mutation (SNP) | VAF 100/225 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMRT2 | c.1262A>G p.Q421R | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); called by muse, varscan2
- FRAS1 | c.10843A>T p.I3615F | Missense Mutation (SNP) | VAF 213/512 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRIT2 | c.1636A>C p.T546P | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP7D3 | c.2501G>A p.R834K | Missense Mutation (SNP) | VAF 135/459 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NPIPB9 | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 58/532 reads (11%) | SIFT tolerated, low confidence (0.15); called by muse, varscan2
- PIK3C2B | c.3953G>A p.R1318K | Missense Mutation (SNP) | VAF 96/198 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RPS6KA6 | c.2172G>T p.E724D | Missense Mutation (SNP) | VAF 233/580 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLC26A4 | c.518C>G p.T173S | Missense Mutation (SNP) | VAF 199/429 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSWIM8 | c.3242C>G p.T1081R (on ENST00000605216 / NM_001242487.2; = p.T1086R on NM_015037.3) | Missense Mutation (SNP) | VAF 122/287 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- BTBD19 | c.255G>T p.V85= | Silent (SNP) | VAF 122/299 reads (41%) | called by muse, mutect2, varscan2
- COL6A3 | c.9270T>G p.A3090= | Silent (SNP) | VAF 59/487 reads (12%) | called by muse, mutect2, varscan2
- MTSS2 | c.1467C>A p.S489= | Silent (SNP) | VAF 94/247 reads (38%) | catalogued as COSV55382585; called by muse, mutect2, varscan2
- MYH13 | c.582G>A p.Q194= | Silent (SNP) | VAF 134/359 reads (37%) | called by muse, mutect2, varscan2
- SLC17A7 | c.1326C>T p.N442= | Silent (SNP) | VAF 127/318 reads (40%) | catalogued as rs971797832, COSV55548445; called by muse, mutect2, varscan2
- SVEP1 | c.8772C>T p.H2924= | Silent (SNP) | VAF 85/189 reads (45%) | catalogued as rs758272920, COSV52836831; called by muse, mutect2, varscan2
- VIP | c.96T>A p.P32= | Silent (SNP) | VAF 121/348 reads (35%) | catalogued as COSV100923938; called by muse, mutect2, varscan2
- ARL1 | c.225-84G>A | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- ATP2A3 | c.2322-18C>G | Intron (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- CTSK | c.120+54C>G | Intron (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- GPR160 | c.*53A>G | 3'UTR (SNP) | VAF 68/140 reads (49%) | called by muse, mutect2, varscan2
- HPN | c.-55G>T | 5'UTR (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- IBTK | c.3431+31C>G | Intron (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- LBX1 | c.*94C>G | 3'UTR (SNP) | VAF 18/43 reads (42%) | catalogued as rs1293231423; called by muse, mutect2, varscan2
- RUFY2 | c.1656-19C>T | Intron (SNP) | VAF 14/261 reads (5%) | called by muse, mutect2
- UCHL5 | c.-117G>T | 5'UTR (SNP) | VAF 22/322 reads (7%) | called by muse, mutect2
